Gene-level copy-number profile of tumor specimen TCGA-02-2470-01A from TCGA case TCGA-02-2470, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.6 years (21,021 days).
Specimen TCGA-02-2470-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.97e9e20e-47b0-4300-8b86-ff736bfff466.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-2470-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9a686968-2e67-49a4-850b-e823bbeea674

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 6,363; copy number 2: 50,097; copy number 3: 3,103; copy number 4: 113; copy number 6: 12; copy number 18: 37; copy number 19: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-02-2470-01A-01D-0784-01): tumor purity 0.53, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 73 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,507,452–22,455,740, 73 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 65 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,954,640–205,134,950, 37 genes, copy number 18: CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2.
- chr7:38,256,337–38,329,643, 12 genes, copy number 6: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2.
- chr11:116,496,899–117,098,437, 16 genes, copy number 19: LINC02151, AP000770.1, LINC02702, BUD13, AP006216.1, ZPR1, APOA5, AP006216.2, AP006216.3, APOA4, APOC3, APOA1, APOA1-AS, SIK3, RNY4P6, AP000936.3.

Autosomal genes at a single copy (total copy number 1): 3,977. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
